Somatic mutation profile of tumor specimen TCGA-AN-A0AL-01A (aliquot TCGA-AN-A0AL-01A-11W-A019-09) from TCGA case TCGA-AN-A0AL, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 41.9 years (15,286 days).
Specimen TCGA-AN-A0AL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6c9095da-a2a4-48c8-be52-bd080946be3f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AN-A0AL-10A (Blood Derived Normal), aliquot TCGA-AN-A0AL-10A-01W-A021-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9a5eb9fe-dc96-43e8-902a-fecd7ae8cab8

The open-access MAF lists 89 somatic variants for this specimen: 74 protein-altering or splice-affecting, 12 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 55, Silent 12, Frame Shift Del 10, Nonsense Mutation 5, Splice Site 3, 5'Flank 2, RNA 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 56/93 reads (60%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ACTL9 | c.956C>A p.A319D | Missense Mutation (SNP) | VAF 20/32 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV61006037; called by muse, mutect2, varscan2
- ADH1C | c.386G>A p.R129K | Missense Mutation (SNP) | VAF 32/136 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV72463493; called by muse, mutect2, varscan2
- AK9 | c.4849G>C p.G1617R | Missense Mutation (SNP) | VAF 43/97 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV69851634; called by muse, mutect2, varscan2
- AKR1C1 | c.741del p.K247Nfs*8 | Frame Shift Del (DEL) | VAF 13/119 reads (11%) | catalogued as rs781870854, COSV101080451; called by mutect2, pindel, varscan2
- ALG2 | c.1138C>T p.P380S | Missense Mutation (SNP) | VAF 62/83 reads (75%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.793); catalogued as COSV53059939; called by muse, mutect2, varscan2
- ASB7 | c.344A>G p.N115S | Missense Mutation (SNP) | VAF 82/502 reads (16%) | SIFT tolerated (0.88); PolyPhen possibly damaging (0.621); catalogued as rs1315289743, COSV58403880; called by muse, mutect2, varscan2
- BAZ1A | c.2848G>C p.D950H | Missense Mutation (SNP) | VAF 61/194 reads (31%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.786); catalogued as COSV62410473; called by muse, mutect2, varscan2
- C2CD6 | c.1130C>A p.P377H | Missense Mutation (SNP) | VAF 95/236 reads (40%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV99631914; called by muse, mutect2, varscan2
- CARD6 | c.595A>G p.R199G | Missense Mutation (SNP) | VAF 62/197 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as COSV54566606; called by muse, mutect2, varscan2
- CCDC144A | c.2795C>G p.T932R | Missense Mutation (SNP) | VAF 53/120 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV60698782; called by muse, mutect2, varscan2
- CCNB3 | c.265G>T p.V89F | Missense Mutation (SNP) | VAF 8/246 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.061); catalogued as COSV99328448; called by muse, mutect2
- CFP | c.1103G>A p.R368Q | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.968); catalogued as rs1438785777, COSV55950430; called by muse, mutect2, varscan2
- COL19A1 | c.296A>T p.E99V | Missense Mutation (SNP) | VAF 152/404 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59574990, COSV59575041; called by muse, varscan2
- CYP26B1 | c.1386C>G p.S462R | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV50012217; called by muse, mutect2, varscan2
- DMD | c.10126C>A p.L3376I | Missense Mutation (SNP) | VAF 16/366 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as CD951686, COSV100625997; called by muse, mutect2
- FAT3 | c.13162C>T p.R4388W | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as rs543168460, COSV53120073; called by muse, mutect2, varscan2
- FZD3 | c.1409C>T p.T470I | Missense Mutation (SNP) | VAF 47/163 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.433); catalogued as COSV53535803; called by muse, mutect2, varscan2
- GOLGA1 | c.125G>C p.G42A | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV60613392; called by muse, mutect2, varscan2
- H3C13 | c.370G>T p.D124Y | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.955); catalogued as COSV58944394; called by muse, mutect2, varscan2
- H3C13 | c.369G>T p.K123N | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.944); catalogued as COSV58944400; called by muse, mutect2, varscan2
- HERC1 | c.5254C>T p.R1752C | Missense Mutation (SNP) | VAF 10/264 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1293668575, COSV101496330; called by muse, mutect2
- HRNR | c.8548C>T p.Q2850* | Nonsense Mutation (SNP) | VAF 15/51 reads (29%) | catalogued as COSV64258940; called by muse, mutect2, varscan2
- HSPA12A | c.1028-1G>A p.X343_splice | Splice Site (SNP) | VAF 50/158 reads (32%) | catalogued as COSV65022562; called by muse, mutect2, varscan2
- IK | c.832G>A p.V278I | Missense Mutation (SNP) | VAF 17/198 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV101341752; called by muse, mutect2
- KCNT2 | c.2962G>T p.E988* | Nonsense Mutation (SNP) | VAF 85/302 reads (28%) | catalogued as COSV54083555; called by muse, mutect2, varscan2
- KIAA1586 | c.1840A>C p.M614L | Missense Mutation (SNP) | VAF 35/160 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0.042); catalogued as COSV66056767; called by muse, mutect2, varscan2
- MAGEE1 | c.287T>C p.I96T | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as rs868928253, COSV100819278; called by muse, mutect2, varscan2
- MAP1A | c.131C>A p.P44Q | Missense Mutation (SNP) | VAF 37/102 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55809476; called by muse, mutect2, varscan2
- NCF2 | c.223T>G p.F75V | Missense Mutation (SNP) | VAF 81/379 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62315689; called by muse, mutect2, varscan2
- NDNF | c.773C>T p.P258L | Missense Mutation (SNP) | VAF 19/129 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as rs761126466, COSV65633701; called by muse, mutect2, varscan2
- NLRP11 | c.1327A>G p.K443E | Missense Mutation (SNP) | VAF 109/282 reads (39%) | SIFT tolerated (0.74); PolyPhen benign (0.018); catalogued as rs764210174, COSV64087653; called by muse, mutect2, varscan2
- NRXN3 | c.2369T>G p.L790* (on ENST00000335750 / NM_001330195.2; = p.L417* on NM_004796.6) | Nonsense Mutation (SNP) | VAF 68/214 reads (32%) | catalogued as COSV59757130; called by muse, mutect2, varscan2
- ODF2 | c.1055A>G p.Q352R (on ENST00000434106 / NM_153433.2; = p.Q328R on NM_002540.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 53/87 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV63546458; called by muse, mutect2, varscan2
- OR52K2 | c.750C>G p.I250M | Missense Mutation (SNP) | VAF 398/929 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.89); catalogued as COSV57835209; called by muse, mutect2, varscan2
- PACS1 | c.1591A>T p.S531C | Missense Mutation (SNP) | VAF 39/172 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.887); catalogued as COSV57697998; called by muse, mutect2, varscan2
- PCDHAC1 | c.215del p.S72Tfs*24 | Frame Shift Del (DEL) | VAF 7/16 reads (44%) | catalogued as COSV53852489; called by mutect2, pindel, varscan2
- PCDHGB4 | c.1231G>T p.E411* | Nonsense Mutation (SNP) | VAF 27/62 reads (44%) | catalogued as COSV53961874; called by muse, mutect2, varscan2
- PLEKHG3 | c.1457A>G p.E486G (on ENST00000394691; = p.E542G on NM_001308147.2) | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.281); catalogued as COSV55980642; called by muse, mutect2, varscan2
- POSTN | c.213G>T p.Q71H | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.139); catalogued as COSV101123247; called by muse, mutect2
- PTPRN2 | c.2518G>A p.V840M | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.529); catalogued as rs1421310773, COSV66104829; called by muse, mutect2, varscan2
- RESF1 | c.3332C>G p.S1111* | Nonsense Mutation (SNP) | VAF 82/242 reads (34%) | catalogued as COSV57022700; called by muse, mutect2, varscan2
- RFPL3 | c.481G>A p.E161K (on ENST00000249007 / NM_001098535.1; = p.E132K on NM_006604.2) | Missense Mutation (SNP) | VAF 41/165 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.916); catalogued as rs778951773, COSV50749546; called by muse, mutect2, varscan2
- RGS1 | c.513T>G p.F171L | Missense Mutation (SNP) | VAF 62/498 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as COSV66505508; called by muse, mutect2, varscan2
- RIPOR3 | c.963C>A p.S321R | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.289); catalogued as rs751601501, COSV50390886; called by muse, mutect2, varscan2
- RTL9 | c.3572C>A p.S1191Y | Missense Mutation (SNP) | VAF 103/298 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV71825681; called by muse, mutect2, varscan2
- SELE | c.80C>G p.S27C | Missense Mutation (SNP) | VAF 25/150 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60975854; called by muse, mutect2, varscan2
- SF1 | c.705C>G p.D235E | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV57114365; called by muse, mutect2, varscan2
- SLC9B1 | c.113C>T p.T38I | Missense Mutation (SNP) | VAF 6/99 reads (6%) | SIFT tolerated (0.27); PolyPhen benign (0.029); catalogued as rs1313941088, COSV99599183; called by muse, mutect2
- SLIT2 | c.3353T>C p.V1118A | Missense Mutation (SNP) | VAF 86/370 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0.009); catalogued as COSV99880923; called by muse, mutect2, varscan2
- SNX32 | c.354G>C p.K118N | Missense Mutation (SNP) | VAF 49/84 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.275); catalogued as COSV57449740; called by muse, mutect2, varscan2
- TCHH | c.856C>A p.L286M | Missense Mutation (SNP) | VAF 39/91 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.735); catalogued as rs749640421, COSV64275356; called by muse, mutect2, varscan2
- TROAP | c.329C>T p.A110V | Missense Mutation (SNP) | VAF 66/102 reads (65%) | SIFT deleterious (0.02); PolyPhen benign (0.023); catalogued as COSV57744598; called by muse, mutect2, varscan2
- TRPV2 | c.833C>A p.A278D | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT deleterious (0.03); PolyPhen benign (0.101); catalogued as COSV58428676; called by muse, mutect2, varscan2
- TTN | c.6450G>T p.M2150I (on ENST00000591111; = p.M2104I on NM_003319.4) | Missense Mutation (SNP) | VAF 76/333 reads (23%) | PolyPhen probably damaging (0.961); catalogued as COSV60107513; called by muse, mutect2, varscan2
- UGT1A6 | c.836G>T p.C279F | Missense Mutation (SNP) | VAF 26/962 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100529527; called by muse, mutect2
- UPRT | c.531G>T p.K177N | Missense Mutation (SNP) | VAF 8/254 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.274); catalogued as COSV100974444; called by muse, mutect2
- USP1 | c.670A>G p.K224E | Missense Mutation (SNP) | VAF 37/115 reads (32%) | SIFT tolerated (0.82); PolyPhen benign (0.033); catalogued as COSV60574582; called by muse, mutect2, varscan2
- WSCD1 | c.1576G>C p.G526R | Missense Mutation (SNP) | VAF 14/21 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58495903; called by muse, mutect2, varscan2
- XPOT | c.917G>C p.W306S | Missense Mutation (SNP) | VAF 83/144 reads (58%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.446); catalogued as COSV60345808; called by muse, mutect2, varscan2
- ZNF718 | c.1285G>A p.G429S | Missense Mutation (SNP) | VAF 65/94 reads (69%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); catalogued as rs782233637, COSV68140451; called by muse, mutect2, varscan2
- ABI3BP | c.2087_2114del p.G696Dfs*30 | Frame Shift Del (DEL) | VAF 16/60 reads (27%) | called by mutect2, pindel, varscan2
- AKR1C2 | c.741del p.K247Nfs*8 | Frame Shift Del (DEL) | VAF 17/93 reads (18%) | called by mutect2, pindel, varscan2
- CC2D2A | c.4053G>C p.W1351C | Missense Mutation (SNP) | VAF 15/528 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CNGA1 | c.146A>G p.E49G | Missense Mutation (SNP) | VAF 5/136 reads (4%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.156); called by muse, mutect2
- EGFLAM | c.2465-17_2478del p.X822_splice | Splice Site (DEL) | VAF 46/292 reads (16%) | called by mutect2, pindel
- FBXO43 | c.1675-13_1678del p.X559_splice | Splice Site (DEL) | VAF 23/154 reads (15%) | called by mutect2, pindel
- GMDS | c.166_194del p.R56* | Frame Shift Del (DEL) | VAF 26/250 reads (10%) | called by mutect2, pindel
- KRTAP10-6 | c.12_33del p.M6* | Frame Shift Del (DEL) | VAF 11/66 reads (17%) | called by mutect2, pindel, varscan2
- MX2 | c.2096_2112del p.L699Rfs*29 | Frame Shift Del (DEL) | VAF 49/137 reads (36%) | called by mutect2, pindel, varscan2
- MYPN | c.3675_3694del p.T1226Hfs*19 | Frame Shift Del (DEL) | VAF 36/213 reads (17%) | called by mutect2, pindel, varscan2
- NF1 | c.527_535delinsTTGA p.D176Vfs*23 | Frame Shift Del (DEL) | VAF 50/111 reads (45%) | called by pindel, varscan2*
- SERPINA11 | c.92_118del p.Q31_Q39del | In Frame Del (DEL) | VAF 78/369 reads (21%) | called by mutect2, pindel, varscan2
- USPL1 | c.986_1002del p.D329Vfs*14 | Frame Shift Del (DEL) | VAF 84/358 reads (23%) | called by mutect2, pindel, varscan2
- AFF4 | c.2379G>A p.K793= | Silent (SNP) | VAF 141/248 reads (57%) | catalogued as COSV54795467, COSV54798693; called by muse, mutect2, varscan2
- ASB2 | c.174G>A p.A58= | Silent (SNP) | VAF 10/21 reads (48%) | catalogued as rs201823942, COSV60110101; called by muse, mutect2, varscan2
- CCDC102B | c.1479G>A p.L493= | Silent (SNP) | VAF 91/176 reads (52%) | catalogued as rs751886467, COSV60143892; called by muse, mutect2, varscan2
- GPA33 | c.108A>G p.G36= | Silent (SNP) | VAF 38/138 reads (28%) | catalogued as COSV100900911; called by muse, mutect2, varscan2
- ITK | c.156G>A p.K52= | Silent (SNP) | VAF 34/53 reads (64%) | catalogued as rs1258351156, COSV70062765; called by muse, mutect2, varscan2
- KIF24 | c.3762C>A p.L1254= | Silent (SNP) | VAF 20/75 reads (27%) | catalogued as COSV52659230; called by muse, mutect2, varscan2
- MCM3 | c.2322C>A p.G774= (on ENST00000229854 / NM_001366374.2; = p.G764= on NM_002388.6 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 107/420 reads (25%) | catalogued as COSV57717880; called by muse, mutect2, varscan2
- OR4X1 | c.681C>T p.N227= | Silent (SNP) | VAF 78/213 reads (37%) | catalogued as rs1175883835, COSV60723060; called by muse, mutect2, varscan2
- PTCHD4 | c.1464A>G p.G488= | Silent (SNP) | VAF 66/159 reads (42%) | catalogued as COSV59786249; called by muse, mutect2, varscan2
- RBL1 | c.2502A>G p.L834= | Silent (SNP) | VAF 27/89 reads (30%) | catalogued as rs775028069, COSV60330317; called by muse, mutect2, varscan2
- ZNF224 | c.1590C>T p.H530= | Silent (SNP) | VAF 125/379 reads (33%) | catalogued as COSV61242442; called by muse, mutect2, varscan2
- ZNF592 | c.396A>G p.S132= | Silent (SNP) | VAF 14/330 reads (4%) | catalogued as rs1210689596, COSV100245668; called by muse, mutect2
- MIR622 | n.78G>T | RNA (SNP) | VAF 23/66 reads (35%) | called by muse, mutect2, varscan2
- Y_RNA | chr7:75514763 G>C | 5'Flank (SNP) | VAF 12/336 reads (4%) | called by muse, mutect2
- ZBTB37 | chr1:173865371 C>G | 5'Flank (SNP) | VAF 8/28 reads (29%) | called by muse, mutect2, varscan2
